Surgical pathology report (de-identified scan), TCGA case TCGA-66-2800, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2800-01A (Primary Tumor).

[page 1 of 3]
Material examined:

Right upper lobe and others

Clinical diagnosis and question

Right upper lobe bronchial carcinoma, status after asbestosis?

REPORT ON FINDINGS

Macroscopy

1) Right upper lobe: inflated, fixed preparation measuring 19 × 14 × 6.5 cm, with predominantly shiny pleural surface, altogether slightly patchy or reticulate, grayish black markings. Laterobasal zone of adhesion over S2 and the border area of segments 2 and 3, where there was a part of the chest wall up to 12 × 9 cm in size including a rib segment 5.8 cm long. In addition a membranous part of the adhesive parietal pleura, fatty in places, 12 × 9 cm in size lying clear over S2 and S1. The latter extensively covered the lateral parts of S2 and bordering sections of S1 and was mainly without adhesion to the visceral pleura. There was another zone of adhesion in a medial direction, at about the point of attachment of the part of the chest wall, attached by a parenchymal flap enclosed by a row of clip sutures 6.5 × 5 × 2 cm in size (part of S6? middle lobe?). A nodular tumor, maximum 6.2 cm in size, at the base of S2, with dirty, whitish section surfaces, also focal grayish yellow softening, sharp and markedly arched distinction from the adjacent parenchymal tumor on one side, on the other side continuous infiltration of the visceral pleura and extension to the parenchymal flap attached medially, where it extended to just by the base of the preparation and the row of clip sutures. In the region of the contact point with the part of the chest wall, blackish thickening of the fused pleural lamina. Central discontinuation of B2 about 1.7 cm distally of the bifurcation in the tumor tissue, also of one of the sub-segment branches of B3. The other bronchial branches free as far as the peripheral sections. About 3.5 cm away from the principal tumor in S1 a second, rather irregularly formed, pale grey tumor 1.6 cm in size in the sub-pleural parenchyma, distance from pulmonary tissue with normal section surfaces to the pleura about 3 mm. Central bronchial resection line located immediately proximal of the segment division point, by the bronchial stump a moderately solid node with dark grey pigment, 2.2 cm in size, damaged in places.

2) Lobar LN (item 12) upper lobe: irregular, predominantly heavily pigmented fragment of 1.8 cm.

3) Lobar LN (item 12) right lower lobe: node with blackish pigment, 1.8 cm in size, with some surrounding tissue.

4) Inter-lobar lymph node (item 11) right: two fragments with largely blackish pigment, of 0.7 and 1.2 cm.

5) Hilar LN (item 10) right: two nodes with grayish black pigment, 1.3 and 1.8 cm in size.

6) Hilar LN (item 10) right (no. II): node 2.7 cm in size, apparently damaged and with blackish pigment, with some surrounding fatty tissue. Borderline dubious small portion of a similar node.

[page 2 of 3]
7) Subcarinal LN (item 7): two preparations 1.2 and 2.3 cm in size with parts of at least 3 nodes with grayish black pigment up to 1.7 cm.

8) Low paratracheal LN (item 4) right: preparation rich in fatty tissue, 4.5 cm in size, with nodes, pale grey in places, blackish in places, between 0.3 and 1.2 cm. A further blackish node or partial node, 0.5 cm in size.

9) Low paratracheal LN (item 4) right + left: fragment of fatty tissue 3.3 cm in size, inclusion of 3 nodes or partial nodes each up to 1.2 cm.

10) Prevascular and retrotracheal node (item 3) right: longitudinal fragment of fatty tissue of 2.5 cm with two nodes or partial nodes with blackish pigment up to 1.2 cm.

11) High paratracheal LN (item 2) right: node 1.4 cm in size with slate grey to reddish section surface and some fatty tissue attached, containing another small, pale grey node 2 mm in size.

12) Lipoma: rounded, flat preparation $3.7 \times 3 \times 1.8$ cm in size, with largely smooth, surface obviously covered by a soft capsule. Section surfaces largely golden yellow, grayish red border area measuring 7 mm in length.

Examined

1) Tumor and part of chest wall, tumor with attached parenchymal flap (where the section surface was marked in color), 2 small apical tumor foci, 2 pieces of parenchyma free of tumor (S1 dorso-apical, S3 ventral, central bronchial resection line and vascular displacement borders, nodes by the bronchial stump (laminated), 4 pieces of parietal pleura.

2) - 7), 9) - 11) Total material in each case (small, isolated node in 11),

8) Isolated node,

12) 2 sections,

20 blocks, Elastica-v.Gieson, PAS, diastasis PAS, iron

Microscopy

1) The large tumor made up of small and large solid links of varying lengths, reticulate or branched in places, and of occasional evident large atypical epithelial cells coated in epidermoid cells, with ample, in the main weakly eosinophilic cytoplasm and nuclei showing major variation in coarse chromatin nuclear structure. Numerous apoptoses, frequently at least five mitoses in a highly magnified viewing field. No inclusion of mucin, instead intercellular bridges were repeatedly identified. In the center of solid tumor cell links, degenerative changes in kariopyknoses and occasionally instances of cells showing dyskeratotic keratosis near small and large areas of necrosis. Basic pulmonary tissue completely destroyed, development of fibrous connective tissue moderately rich in cells with inclusion of inflammatory cells and vessels with thick walls, some of which were filled with tumor cell links. Pleural border exceeded by tumor over a broad area in the region of a lobar cleft, also incursion into the visceral pleura over a broad area, where the adhesive part of the parietal pleura was free of tumor, only fibrotic. In addition here more pronounced chronic inflammatory cell

[page 3 of 3]
infiltrate. Towards the exterior including transversely striped muscle and intact rib bones with hematopoietic cells of all kinds and to a lesser extent fat cells in the marrow cavity. In the small tumor focus also nests and links of a solid, large cell tumor with characteristics of squamous cell epithelium structure, with here a short stretch of replacement of original respiratory epithelium of a peripheral bronchus by atypical squamous cell epithelium. Also destruction of the underlying pulmonary tissue, which was replaced by collagen and elastic connective tissue, enclosed follicular lymphocyte aggregate and other inflammatory cells. Partially widened airways in the pulmonary tissue free of tumor, slight deposition of anthracotic pigment in peribronchiolovascular connective tissue and alveolar parenchyma with quite predominantly soft interstices. No evidence of tumor at the displacement borders of the bronchus and large pulmonary vessels, respiratory mucosa normal. Lymph nodes at the hilus with deposition of anthracotic pigment, accumulation of large macrophages and a few secondary follicles. Adjacent lobes of the parietal pleura mainly entirely soft, only stretches of development of slightly fibrotic connective tissue. Substantial adjacent fatty tissue in places.

2) - 11) Lymph nodes and parts of lymph nodes of various sizes with only occasional secondary follicles, expansion of the paracortical or T zone, increase in capillary vessels in places, deposition of anthracotic pigment of varying thicknesses and small focus of trabecular sclerosis. Small nerve stems and vessels of various lumen sizes in the surrounding fatty tissue, including in sample 7) a small artery.

12) Fatty tissue in the shape of small lobes in places made up of single-vacuole fat cells, several enclosed capillary vessels and narrow and broad bands of transversely striped muscle, which were also found in the border areas.

EVALUATION

Right upper pulmonary lobe with one large and one small focus of a poorly differentiated, large cell squamous cell carcinoma not tending towards keratinization. The large tumor located in S2 and adjacent parts of segment 3, extending from the center to the periphery, encroaching over the part of segment 6 or the middle lobe removed and infiltrating the pleural over a broad area, is therefore probably primarily a peripheral bronchopulmonary carcinoma with a satellite node in the lobe on the same side. The adhesive part of the parietal pleura above the tumor was not infiltrated by the tumor, and the soft tissue and the resected part of the ribs were also free of tumor. Partial necrotic alteration of the principal tumor, with vascular incursions in this as well. Pulmonary parenchyma free of tumor largely normal, no hyaline pleural plaque in the resected pleura. Displacement borders of bronchus and large pulmonary vessels and all removed lymph nodes free of tumor. An intramuscular lipoma in sample 12) without criteria for malignancy.

Tumor formula in accordance with the foregoing pT4 pN0 V1 R0 equivalent to stage IIIB.

Morphology:

8070/3

Topography:

C34.1

Source: NCI Genomic Data Commons file 26821a17-eb69-41f3-affd-3543eb4957af (TCGA-66-2800.06D8266A-1FC8-4082-8A06-178DC57639C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).